Somatic mutation profile of tumor specimen 0DSHT7 from CCDI case PBCGWP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Superior wall of nasopharynx; Age at diagnosis: 13.3 years (4,842 days).
Specimen 0DSHT7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 519364db-563d-4ab6-b90d-c8f44befdfba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSHTC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5141f02-42be-4ab7-8900-71ffeadbf217

The open-access MAF lists 77 somatic variants for this specimen: 49 protein-altering or splice-affecting, 18 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 18, 3'UTR 4, Frame Shift Del 4, Intron 3, Splice Site 2, 5'UTR 1, In Frame Del 1, RNA 1, Splice Region 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1605C>A p.N535K | Missense Mutation (SNP) | VAF 41/406 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519792, COSV52800481, COSV52801581; ClinVar: likely pathogenic; called by muse, mutect2
- ASXL1 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 59/456 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as rs1005458245, COSV60104557; called by muse, mutect2, varscan2
- CHD5 | c.3590C>T p.T1197M | Missense Mutation (SNP) | VAF 63/511 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52428683; called by muse, mutect2, varscan2
- DOK6 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 31/320 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs780042576, COSV66933129, COSV66938262; called by muse, mutect2, varscan2
- DUSP3 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 66/493 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1380319519, COSV56825154; called by muse, mutect2, varscan2
- ERMP1 | c.1480_1483del p.L494Mfs*6 | Frame Shift Del (DEL) | VAF 64/619 reads (10%) | catalogued as rs760179064; called by mutect2, varscan2
- FASN | c.5879C>T p.A1960V | Missense Mutation (SNP) | VAF 64/598 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.131); catalogued as rs139421825; called by muse, mutect2
- GABRB2 | c.1408C>T p.R470C (on ENST00000274547; = p.R432C on NM_000813.3) | Missense Mutation (SNP) | VAF 49/618 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs774391847, COSV50905801; called by muse, mutect2
- GABRR1 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 81/807 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs371702531; called by muse, mutect2
- HHLA2 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 66/784 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1455892963, COSV63316566; called by muse, mutect2
- HMGB1 | c.26C>G p.P9R | Missense Mutation (SNP) | VAF 50/457 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV58104357; called by muse, mutect2, varscan2
- JAKMIP3 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 69/486 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as rs745792121, COSV53824595; called by muse, mutect2, varscan2
- KAT6A | c.3039+5C>G | Splice Region (SNP) | VAF 39/406 reads (10%) | catalogued as rs200182664; called by muse, mutect2, varscan2
- KAT6B | c.5386G>A p.E1796K | Missense Mutation (SNP) | VAF 49/556 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs201792033, COSV54745196; called by muse, mutect2
- MS4A7 | c.601T>G p.Y201D | Missense Mutation (SNP) | VAF 172/907 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55729548; called by muse, mutect2, varscan2
- NLRP2 | c.2812G>A p.G938R | Missense Mutation (SNP) | VAF 75/664 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.801); catalogued as rs768507334; called by muse, mutect2, varscan2
- PRSS41 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.513); catalogued as rs984970689, COSV68671965; called by muse, mutect2
- SCN2A | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 48/958 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761161877, COSV99332298; called by muse, mutect2
- SCYL3 | c.534C>G p.F178L | Missense Mutation (SNP) | VAF 79/681 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.801); catalogued as COSV63047301; called by muse, mutect2, varscan2
- TBKBP1 | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 56/440 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs771594071, COSV100659097; called by muse, mutect2, varscan2
- TFEB | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.2); catalogued as rs371923346; called by muse, mutect2, varscan2
- TRIM51 | c.956C>G p.P319R | Missense Mutation (SNP) | VAF 78/739 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.807); catalogued as COSV55263539; called by muse, mutect2, varscan2
- TRRAP | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 36/696 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs782009444, COSV62843436; called by muse, mutect2
- TTC33 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 68/650 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs568573931; called by muse, varscan2
- ABCG1 | c.707C>A p.P236Q | Missense Mutation (SNP) | VAF 72/460 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADCY2 | c.887T>C p.I296T | Missense Mutation (SNP) | VAF 76/829 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ADGRV1 | c.15043A>G p.I5015V | Missense Mutation (SNP) | VAF 73/592 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCOR | c.2641del p.D881Tfs*12 | Frame Shift Del (DEL) | VAF 69/266 reads (26%) | called by mutect2, varscan2
- CLMN | c.1188C>A p.S396R | Missense Mutation (SNP) | VAF 21/234 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.182); called by mutect2, varscan2
- DOCK6 | c.4193del p.I1398Tfs*6 | Frame Shift Del (DEL) | VAF 28/260 reads (11%) | called by mutect2, varscan2
- E4F1 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF3A | c.1760T>G p.I587S | Missense Mutation (SNP) | VAF 82/810 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- FAM71B | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 49/563 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAP | c.1549+1G>A p.X517_splice | Splice Site (SNP) | VAF 34/354 reads (10%) | called by muse, mutect2
- FOLH1 | c.65G>A p.C22Y | Missense Mutation (SNP) | VAF 68/754 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); called by muse, mutect2
- FRAS1 | c.8388C>A p.N2796K | Missense Mutation (SNP) | VAF 72/628 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- GGNBP2 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 37/356 reads (10%) | called by muse, mutect2, varscan2
- GLB1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 97/888 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KIF7 | c.2318A>G p.E773G | Missense Mutation (SNP) | VAF 37/382 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- LMNB1 | c.97_99del p.K33del | In Frame Del (DEL) | VAF 31/294 reads (11%) | called by mutect2, varscan2
- NLN | c.930G>C p.K310N | Missense Mutation (SNP) | VAF 68/813 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2
- NRK | c.1338del p.F446Lfs*8 | Frame Shift Del (DEL) | VAF 60/342 reads (18%) | called by mutect2, varscan2
- NUAK2 | c.703T>G p.S235A | Missense Mutation (SNP) | VAF 53/534 reads (10%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC23A3 | c.1172G>T p.G391V (on ENST00000409878 / NM_001144889.2; = p.G274V on NM_144712.5) | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC35E1 | c.631-1G>A p.X211_splice | Splice Site (SNP) | VAF 68/648 reads (10%) | called by muse, mutect2
- SNPH | c.1036G>C p.D346H | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.73); called by muse, mutect2
- TAFA1 | c.371T>C p.I124T | Missense Mutation (SNP) | VAF 50/663 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2
- TRAK1 | c.1337G>C p.R446P (on ENST00000327628 / NM_001349247.2; = p.R388P on NM_014965.5) | Missense Mutation (SNP) | VAF 48/456 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.858); called by muse, varscan2
- ZNF131 | c.1571A>G p.Y524C (on ENST00000509156 / NM_001330707.2; = p.Y490C on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/532 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2
- ADAT3 | c.294C>T p.R98= | Silent (SNP) | VAF 33/323 reads (10%) | catalogued as rs1043158025; called by muse, mutect2, varscan2
- ALG13 | c.2913C>T p.S971= | Silent (SNP) | VAF 91/445 reads (20%) | catalogued as COSV52636722; called by muse, mutect2, varscan2
- ANKRD11 | c.6048C>T p.P2016= | Silent (SNP) | VAF 40/446 reads (9%) | catalogued as rs748892371; called by muse, mutect2
- BRF2 | c.372C>A p.I124= | Silent (SNP) | VAF 138/635 reads (22%) | called by muse, mutect2, varscan2
- CD226 | c.471G>A p.T157= | Silent (SNP) | VAF 60/585 reads (10%) | catalogued as rs768831282, COSV99711050; called by muse, mutect2, varscan2
- CSMD1 | c.3417C>T p.A1139= (on ENST00000520002; = p.A1138= on NM_033225.6) | Silent (SNP) | VAF 64/876 reads (7%) | catalogued as rs374314633; called by muse, mutect2
- EPPK1 | c.13020G>A p.K4340= | Silent (SNP) | VAF 18/950 reads (2%) | called by muse, mutect2
- GOLGA8H | c.1842C>A p.G614= | Silent (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- HIP1R | c.66C>T p.A22= | Silent (SNP) | VAF 14/235 reads (6%) | called by muse, mutect2
- IVNS1ABP | c.246T>C p.A82= | Silent (SNP) | VAF 56/516 reads (11%) | called by muse, mutect2, varscan2
- N4BP1 | c.2511C>T p.P837= | Silent (SNP) | VAF 87/806 reads (11%) | called by muse, mutect2, varscan2
- NARS1 | c.1011C>T p.H337= | Silent (SNP) | VAF 40/375 reads (11%) | catalogued as rs747987253, COSV56878768; called by muse, mutect2, varscan2
- NELFB | c.1410C>T p.C470= | Silent (SNP) | VAF 26/251 reads (10%) | catalogued as rs773352529; called by muse, mutect2, varscan2
- OR51V1 | c.417G>T p.L139= | Silent (SNP) | VAF 132/714 reads (18%) | called by muse, mutect2, varscan2
- POU3F2 | c.396A>G p.Q132= | Silent (SNP) | VAF 34/279 reads (12%) | catalogued as rs546800926; called by muse, mutect2, varscan2
- RARRES1 | c.189G>A p.A63= | Silent (SNP) | VAF 20/398 reads (5%) | called by muse, mutect2
- TRAPPC13 | c.834T>C p.D278= | Silent (SNP) | VAF 78/643 reads (12%) | called by muse, mutect2, varscan2
- ZNF862 | c.1650C>T p.D550= | Silent (SNP) | VAF 48/534 reads (9%) | called by muse, mutect2
- AKAP17A | c.*89C>G | 3'UTR (SNP) | VAF 5/34 reads (15%) | catalogued as rs1248762457; called by muse, mutect2
- C7orf66 | n.347G>T | RNA (SNP) | VAF 81/930 reads (9%) | catalogued as rs1249743711; called by muse, mutect2
- CCDC66 | c.544+22C>A | Intron (SNP) | VAF 33/215 reads (15%) | called by muse, mutect2, varscan2
- FKBP9 | c.704-828G>T | Intron (SNP) | VAF 36/434 reads (8%) | called by muse, mutect2
- FRMPD2 | c.567+17G>T | Intron (SNP) | VAF 48/372 reads (13%) | called by muse, mutect2, varscan2
- HTRA2 | c.-52C>T | 5'UTR (SNP) | VAF 35/253 reads (14%) | called by muse, varscan2
- MPDU1 | c.*48G>C | 3'UTR (SNP) | VAF 25/192 reads (13%) | called by muse, mutect2, varscan2
- NFIA | c.*154A>T | 3'UTR (SNP) | VAF 58/570 reads (10%) | called by muse, mutect2
- NMT1 | chr17:45061279 A>G | 5'Flank (SNP) | VAF 7/94 reads (7%) | catalogued as COSV51959175, COSV51959284; called by muse, mutect2
- PLA2G12A | c.*71C>T | 3'UTR (SNP) | VAF 27/231 reads (12%) | called by muse, mutect2, varscan2
